Somatic mutation profile of tumor specimen TCGA-FG-7637-01A (aliquot TCGA-FG-7637-01A-11D-2086-08) from TCGA case TCGA-FG-7637, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 49.5 years (18,084 days).
Specimen TCGA-FG-7637-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d7b815e-ef1b-4fc5-9b65-f070656c7f4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-7637-10A (Blood Derived Normal), aliquot TCGA-FG-7637-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b40590f5-0ece-495c-8605-d5de8e302f35

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 43/93 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD26 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV63091957; called by muse, mutect2, varscan2
- ARID1A | c.4093C>T p.Q1365* | Nonsense Mutation (SNP) | VAF 60/166 reads (36%) | catalogued as COSV61377321; called by muse, mutect2, varscan2
- BAG6 | c.1239T>G p.N413K | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.343); catalogued as COSV52993343; called by muse, mutect2, varscan2
- C12orf50 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV53897473; called by muse, mutect2, varscan2
- FRAS1 | c.1137C>A p.C379* | Nonsense Mutation (SNP) | VAF 8/157 reads (5%) | catalogued as COSV53630763; called by muse, mutect2
- INPPL1 | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.469); catalogued as COSV53357783; called by muse, mutect2, varscan2
- KIF20A | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs756187494, COSV67510320; called by muse, mutect2, varscan2
- KIR3DL2 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs745524198, COSV99551998; called by muse, mutect2, varscan2
- LIMA1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 59/134 reads (44%) | catalogued as COSV57967454; called by muse, mutect2, varscan2
- NLE1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748512588, COSV100680834, COSV62604297; called by muse, mutect2, varscan2
- OR5D18 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs768748128, COSV100450684, COSV61736976; called by muse, mutect2, varscan2
- PIGZ | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV53014214; called by muse, mutect2, varscan2
- PPP2CA | c.793T>A p.Y265N | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51538647; called by muse, mutect2, varscan2
- RFX6 | c.1850T>A p.F617Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.012); catalogued as COSV60587462; called by muse, mutect2
- SEL1L | c.2068T>G p.F690V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV60921628; called by muse, mutect2, varscan2
- SRPK2 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV61963034; called by muse, mutect2, varscan2
- TLL2 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.935); catalogued as rs141438733; called by muse, mutect2, varscan2
- TRMT13 | c.1087T>G p.Y363D | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV61583599; called by muse, mutect2, varscan2
- TTC30A | c.1250A>G p.D417G | Missense Mutation (SNP) | VAF 10/360 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV63101999; called by muse, mutect2
- ZBTB20 | c.2075dup p.A693Cfs*33 (on ENST00000474710 / NM_001164342.2; = p.A620Cfs*33 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs777745612; called by mutect2, varscan2
- ARID1A | c.5842_5843del p.S1948Pfs*14 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | called by pindel, varscan2
- MUC2 | c.3257G>A p.G1086E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TOM1 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 103/199 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ABCA3 | c.336C>T p.S112= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs138952710, COSV100068179; called by muse, mutect2, varscan2
- GPR180 | c.756A>G p.Q252= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV65385942; called by mutect2, varscan2
- OGA | c.93G>T p.P31= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs746744543, COSV63382587; called by muse, mutect2, varscan2
- OR2G6 | c.273C>T p.T91= | Silent (SNP) | VAF 67/166 reads (40%) | catalogued as COSV100598052, COSV58575338; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2319C>T p.P773= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs1328881593, COSV54762419; called by muse, mutect2, varscan2
- DST | c.4297-4658A>C | Intron (SNP) | VAF 22/169 reads (13%) | catalogued as rs1305180016, COSV99758222; called by muse, mutect2, varscan2
